Somatic mutation profile of tumor specimen TCGA-A5-A7WJ-01A (aliquot TCGA-A5-A7WJ-01A-12D-A34Q-09) from TCGA case TCGA-A5-A7WJ, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G2; Age at diagnosis: 65.0 years (23,723 days).
Specimen TCGA-A5-A7WJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 47d2d84d-d7d7-4278-971d-4e12c2c7bff8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A5-A7WJ-10A (Blood Derived Normal), aliquot TCGA-A5-A7WJ-10A-01D-A34Q-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4fa415bf-ef71-438e-b826-e52befc267b6

The open-access MAF lists 847 somatic variants for this specimen: 651 protein-altering or splice-affecting, 177 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 418, Silent 177, Frame Shift Del 158, Frame Shift Ins 28, Nonsense Mutation 24, Splice Site 10, Intron 7, In Frame Del 7, Splice Region 4, RNA 4, 3'Flank 3, 5'UTR 3.

Variants (750 of 847; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB4 | c.1015del p.S339Qfs*3 | Frame Shift Del (DEL) | VAF 9/22 reads (41%) | catalogued as rs753104429, CD034702, COSV55939298; ClinVar: pathogenic; called by mutect2, varscan2
- ADNP | c.2187dup p.R730Tfs*5 | Frame Shift Ins (INS) | VAF 24/62 reads (39%) | catalogued as rs1555809987; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- ASPM | c.5149del p.I1717* | Frame Shift Del (DEL) | VAF 4/18 reads (22%) | catalogued as rs199422167, CD077387; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ATM | c.640del p.S214Pfs*16 | Frame Shift Del (DEL) | VAF 29/67 reads (43%) | catalogued as rs786204543; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- CHRNA1 | c.1072C>T p.R358W (on ENST00000261007 / NM_001039523.3; = p.R333W on NM_000079.4) | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs374391312, CM086805; ClinVar: uncertain significance / pathogenic; called by muse, mutect2
- ERBB2 | c.2198C>T p.T733I | Missense Mutation (SNP) | VAF 24/39 reads (62%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54064293; called by muse, mutect2, varscan2
- FBXW7 | c.1393C>T p.R465C (on ENST00000281708 / NM_001349798.2; = p.R385C on NM_018315.5) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by muse, varscan2
- GRHPR | c.478G>A p.G160R | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs180177312, CM073114, COSV58941586; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HNF1A | c.864del p.P291Qfs*51 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | catalogued as rs762703502, CM1412341, CX035684, COSV104379772; ClinVar: pathogenic; called by mutect2, varscan2
- KCNH2 | c.2892del p.G965Efs*9 | Frame Shift Del (DEL) | VAF 14/42 reads (33%) | catalogued as rs794728462, CD097571, COSV51237651; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- LRPPRC | c.3147del p.A1051Hfs*6 | Frame Shift Del (DEL) | VAF 30/55 reads (55%) | catalogued as rs769022521; ClinVar: pathogenic; called by mutect2, varscan2
- PCDH15 | c.4990dup p.M1664Nfs*18 (on ENST00000644397 / NM_001354429.2; = p.M1606Nfs*18 on NM_001142771.2) | Frame Shift Ins (INS) | VAF 10/34 reads (29%) | catalogued as rs766484375; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- PIGO | c.2191del p.R731Vfs*17 | Frame Shift Del (DEL) | VAF 41/111 reads (37%) | catalogued as rs760848629; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIK3CA | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 27/51 reads (53%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs772110575, COSV55879949, COSV56003293; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PMS2 | c.1239dup p.D414Rfs*44 | Frame Shift Ins (INS) | VAF 30/100 reads (30%) | catalogued as rs267608159; ClinVar: pathogenic; called by mutect2, varscan2
- PTEN | c.783_784del p.N262Qfs*35 | Frame Shift Del (DEL) | VAF 36/81 reads (44%) | catalogued as rs1554825249; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- RAD50 | c.2165del p.K722Rfs*14 | Frame Shift Del (DEL) | VAF 10/21 reads (48%) | catalogued as rs397507178, COSV54758496; ClinVar: pathogenic; called by mutect2, varscan2
- A1BG | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); catalogued as rs1280350283, COSV99568395; called by muse, mutect2, varscan2
- ABCC4 | c.3655del p.I1219Sfs*11 | Frame Shift Del (DEL) | VAF 14/34 reads (41%) | catalogued as rs756859429, COSV65316407; called by mutect2, varscan2
- ABL1 | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs775748939, COSV59342753; called by mutect2, varscan2
- ABRAXAS2 | c.799A>G p.S267G | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.088); catalogued as rs766863439; called by muse, mutect2, varscan2
- ACKR1 | c.736C>A p.L246M | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100929482; called by muse, mutect2, varscan2
- ADCY9 | c.3523G>A p.G1175R | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1158584676; called by muse, mutect2, varscan2
- ADD1 | c.1076C>A p.P359Q | Missense Mutation (SNP) | VAF 56/112 reads (50%) | SIFT tolerated (0.62); PolyPhen benign (0.206); catalogued as COSV99296893; called by muse, mutect2, varscan2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 26/55 reads (47%) | catalogued as rs760140619; called by mutect2, varscan2
- ALAS1 | c.606C>G p.F202L | Missense Mutation (SNP) | VAF 35/66 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV59627647; called by muse, mutect2, varscan2
- ALDH5A1 | c.1082C>T p.A361V | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.151); catalogued as rs763860786; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALOX15 | c.1715C>T p.T572M | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs761098208, COSV99541831; called by muse, mutect2, varscan2
- AMBRA1 | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100092801; called by muse, mutect2, varscan2
- ANKK1 | c.1372G>A p.E458K | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58273709; called by muse, mutect2, varscan2
- ANKLE2 | c.2521G>A p.A841T | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370540397; called by muse, mutect2, varscan2
- ANKRD12 | c.2169del p.K723Nfs*45 | Frame Shift Del (DEL) | VAF 19/50 reads (38%) | catalogued as rs1469889281; called by mutect2, varscan2
- AP2M1 | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as COSV99490513; called by muse, mutect2, varscan2
- ARHGAP20 | c.2278_2279del p.S760Ffs*6 | Frame Shift Del (DEL) | VAF 20/46 reads (43%) | catalogued as rs761746855; called by pindel, varscan2
- ARHGAP29 | c.3448G>A p.A1150T | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs149136237, COSV53109080; called by muse, mutect2
- ARHGAP36 | c.1316G>A p.R439H | Missense Mutation (SNP) | VAF 31/55 reads (56%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.893); catalogued as rs752116998, COSV52264748; called by muse, mutect2, varscan2
- ARHGDIA | c.395C>T p.T132M | Missense Mutation (SNP) | VAF 41/82 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.652); catalogued as COSV53907323; called by muse, mutect2, varscan2
- ARHGEF2 | c.2627C>T p.A876V (on ENST00000361247 / NM_001162383.2; = p.A848V on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.262); catalogued as rs1259465979, COSV58111850; called by muse, mutect2, varscan2
- ARHGEF28 | c.3527G>A p.R1176H | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs889538743, COSV55256734; called by muse, varscan2
- ARMH4 | c.197C>A p.P66H | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.874); catalogued as rs1452798590; called by muse, mutect2, varscan2
- ARV1 | c.518del p.K173Sfs*8 | Frame Shift Del (DEL) | VAF 26/117 reads (22%) | catalogued as rs544784472, COSV59618356; called by mutect2, varscan2
- ASPM | c.7990G>C p.V2664L | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.122); catalogued as COSV54138820; called by muse, mutect2, varscan2
- ATP11A | c.524C>T p.T175M | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.455); catalogued as rs189256530, COSV52113694; called by muse, mutect2, varscan2
- ATP7B | c.3671G>A p.R1224Q | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.83); catalogued as rs532177115, COSV54434699, COSV54435171; called by muse, mutect2, varscan2
- B4GALNT4 | c.918dup p.R307Afs*98 | Frame Shift Ins (INS) | VAF 14/31 reads (45%) | catalogued as rs770737105; called by mutect2, varscan2
- BCL9L | c.3380dup p.P1128Tfs*42 | Frame Shift Ins (INS) | VAF 17/37 reads (46%) | catalogued as rs751794665; called by mutect2, varscan2
- BICRA | c.2935dup p.A979Gfs*86 | Frame Shift Ins (INS) | VAF 36/70 reads (51%) | catalogued as rs756990560; called by mutect2, varscan2
- BMP2K | c.1628C>A p.A543D | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.203); catalogued as COSV58594023; called by muse, mutect2
- BTBD2 | c.1349G>A p.R450H | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs543463977, COSV55307701; called by muse, mutect2, varscan2
- C1QTNF7 | c.239-1G>A p.X80_splice | Splice Site (SNP) | VAF 20/41 reads (49%) | catalogued as rs769216955; called by muse, varscan2
- C2orf42 | c.1230dup p.R411Tfs*29 | Frame Shift Ins (INS) | VAF 12/82 reads (15%) | catalogued as rs1214126095; called by mutect2, varscan2
- C3orf84 | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.125); catalogued as rs781681179, COSV100234279; called by muse, mutect2, varscan2
- C5 | c.1207G>C p.D403H | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.365); catalogued as COSV56329111; called by muse, mutect2, varscan2
- CACYBP | c.215C>T p.T72M | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.592); catalogued as rs1430522161, COSV100871593; called by muse, mutect2
- CALCRL | c.48del p.F16Lfs*2 | Frame Shift Del (DEL) | VAF 30/70 reads (43%) | catalogued as rs1486659949; called by mutect2, pindel, varscan2
- CAMSAP3 | c.3629G>A p.R1210H | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs766316625; called by muse, mutect2, varscan2
- CASKIN2 | c.3364del p.R1122Gfs*38 | Frame Shift Del (DEL) | VAF 42/91 reads (46%) | catalogued as COSV100050119; called by mutect2, pindel, varscan2
- CASP2 | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.018); catalogued as rs769956463, COSV60081895; called by muse, mutect2, varscan2
- CCDC82 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.335); catalogued as COSV53592377; called by muse, mutect2, varscan2
- CD72 | c.266G>A p.R89H | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs757339870, COSV52411435; called by muse, mutect2, varscan2
- CDC14B | c.562_564del p.K188del | In Frame Del (DEL) | VAF 12/64 reads (19%) | catalogued as rs1300748932; called by pindel, varscan2
- CDC42BPB | c.2494C>T p.R832W | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs760767641, COSV63474415; called by muse, mutect2, varscan2
- CDH10 | c.1625-1G>T p.X542_splice | Splice Site (SNP) | VAF 10/23 reads (43%) | catalogued as COSV52581310; called by muse, mutect2, varscan2
- CDK11B | c.1642C>T p.R548C | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.406); catalogued as rs1339904146; called by muse, mutect2, varscan2
- CELA2B | c.209C>T p.T70M | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756679268; called by muse, mutect2, varscan2
- CEP350 | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 51/211 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs780482124; called by muse, mutect2, varscan2
- CERK | c.1428del p.K477Rfs*74 | Frame Shift Del (DEL) | VAF 31/71 reads (44%) | catalogued as rs761362852; called by mutect2, pindel, varscan2
- CHD8 | c.5314C>T p.R1772C (on ENST00000646647 / NM_001170629.2; = p.R1493C on NM_020920.4) | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs1286064384, COSV63036586; called by muse, mutect2, varscan2
- CHFR | c.346G>A p.V116M | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs765096474, COSV99905678; called by muse, mutect2, varscan2
- CHRFAM7A | c.790C>T p.R264C | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as rs1423422981; called by mutect2, varscan2
- CHRNA7 | c.1060C>T p.R354C | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as rs568931594, COSV60974599; called by mutect2, varscan2
- CLCN2 | c.1142dup p.G382Wfs*21 | Frame Shift Ins (INS) | VAF 8/90 reads (9%) | catalogued as rs1217596296; called by mutect2, pindel
- CLCN4 | c.2083C>T p.R695C | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as rs752295778; called by muse, mutect2, varscan2
- CLDN9 | c.537del p.L180Sfs*196 | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | catalogued as rs763852712; called by mutect2, varscan2
- CNOT3 | c.1033G>A p.A345T | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs199960898, COSV55360860; called by muse, mutect2, varscan2
- COG2 | c.380del p.K127Rfs*5 | Frame Shift Del (DEL) | VAF 25/100 reads (25%) | catalogued as rs1188081815, COSV100794718; called by mutect2, varscan2
- COL7A1 | c.3134C>T p.T1045M | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.083); catalogued as rs760854147; called by muse, mutect2, varscan2
- CROCC | c.3572G>A p.R1191Q | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs201760356, COSV100978142; called by muse, varscan2
- CTDSP2 | c.550C>T p.R184W | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779108955; called by muse, mutect2, varscan2
- CYBB | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV66086234; called by muse, mutect2, varscan2
- CYGB | c.235C>T p.R79W | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373180768; called by muse, mutect2, varscan2
- CYP27B1 | c.1376G>A p.R459H | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762550487, COSV56984641, COSV56986993; called by muse, mutect2, varscan2
- CYP7B1 | c.392del p.N131Ifs*4 | Frame Shift Del (DEL) | VAF 19/42 reads (45%) | catalogued as rs748480664, COSV59597772; called by mutect2, pindel, varscan2
- DCST2 | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs376847671, COSV55055109; called by muse, mutect2, varscan2
- DDX46 | c.298C>T p.R100W | Missense Mutation (SNP) | VAF 11/124 reads (9%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs768363770; called by muse, mutect2
- DENND4B | c.763G>A p.V255M | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.068); catalogued as rs751314491, COSV63410129; called by muse, mutect2, varscan2
- DGKA | c.2176del p.R726Afs*9 | Frame Shift Del (DEL) | VAF 28/56 reads (50%) | catalogued as COSV59384233; called by mutect2, varscan2
- DIAPH3 | c.958del p.I320Lfs*20 (on ENST00000400324 / NM_001042517.2; = p.I57Lfs*20 on NM_030932.3) | Frame Shift Del (DEL) | VAF 32/71 reads (45%) | catalogued as rs755069320; called by mutect2, varscan2
- DIS3 | c.2032del p.I678Ffs*59 | Frame Shift Del (DEL) | VAF 29/64 reads (45%) | catalogued as rs771690280; called by mutect2, varscan2
- DIS3 | c.1150C>T p.R384C | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs146500302, COSV66707916; called by muse, mutect2, varscan2
- DLGAP2 | c.932C>T p.T311M | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.785); catalogued as rs773355695, COSV101421011, COSV70099049; called by muse, mutect2
- DNAH7 | c.3221dup p.L1074Ffs*4 | Frame Shift Ins (INS) | VAF 16/50 reads (32%) | catalogued as rs763352877; called by mutect2, varscan2
- DNAJB4 | c.116_118del p.P39del | In Frame Del (DEL) | VAF 28/72 reads (39%) | catalogued as rs759396618; called by pindel, varscan2
- DNASE2B | c.953G>A p.R318H | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs146223730; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 23/53 reads (43%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DPYSL2 | c.1249G>A p.V417I | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs771160273, COSV60784542; called by muse, mutect2, varscan2
- DSP | c.1765G>T p.E589* | Nonsense Mutation (SNP) | VAF 10/54 reads (19%) | catalogued as COSV65793469, COSV65793527; called by muse, mutect2, varscan2
- DSTN | c.308dup p.L103Ffs*12 | Frame Shift Ins (INS) | VAF 15/30 reads (50%) | catalogued as rs750962255; called by mutect2, varscan2
- DYNC1H1 | c.483del p.F161Lfs*52 | Frame Shift Del (DEL) | VAF 12/77 reads (16%) | catalogued as rs1566996283; called by mutect2, pindel, varscan2
- DYNC1I2 | c.50G>A p.R17Q | Missense Mutation (SNP) | VAF 12/129 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs1254884865; called by muse, mutect2, varscan2
- E2F1 | c.631C>T p.R211* | Nonsense Mutation (SNP) | VAF 7/16 reads (44%) | catalogued as rs1223127537, COSV55774398; called by muse, mutect2, varscan2
- EIF4G3 | c.1689dup p.V564Sfs*12 | Frame Shift Ins (INS) | VAF 8/44 reads (18%) | catalogued as rs1558140642; called by mutect2, varscan2
- EIF4H | c.537dup p.M180Hfs*35 | Frame Shift Ins (INS) | VAF 28/60 reads (47%) | catalogued as rs781861584; called by mutect2, varscan2
- ELAVL3 | c.47del p.G16Afs*35 | Frame Shift Del (DEL) | VAF 12/22 reads (55%) | catalogued as rs751148694; called by mutect2, varscan2
- EPRS1 | c.3060del p.E1021Kfs*17 | Frame Shift Del (DEL) | VAF 47/172 reads (27%) | catalogued as rs1394740497; called by mutect2, pindel, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 56/76 reads (74%) | catalogued as rs775950025; called by mutect2, varscan2
- ETV3L | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs745957498, COSV101485629; called by muse, mutect2, varscan2
- EWSR1 | c.818G>A p.S273N | Missense Mutation (SNP) | VAF 53/103 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs778951638; called by muse, mutect2, varscan2
- FAHD2A | c.842del p.P281Qfs*26 | Frame Shift Del (DEL) | VAF 28/66 reads (42%) | catalogued as rs766589051; called by mutect2, pindel, varscan2
- FAM135B | c.1074del p.K358Nfs*5 | Frame Shift Del (DEL) | VAF 33/75 reads (44%) | catalogued as COSV52709988; called by mutect2, pindel, varscan2
- FAM47A | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 108/210 reads (51%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs373732464, COSV60494516; called by muse, mutect2, varscan2
- FAM50A | c.866G>A p.R289Q | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50130720; called by muse, mutect2, varscan2
- FBLN2 | c.2330C>T p.P777L | Missense Mutation (SNP) | VAF 38/75 reads (51%) | SIFT tolerated (0.4); PolyPhen benign (0.01); catalogued as rs781322694, COSV99852698; called by muse, mutect2, varscan2
- FBXL18 | c.1552_1553del p.S518Cfs*183 | Frame Shift Del (DEL) | VAF 22/63 reads (35%) | catalogued as rs1205693228; called by pindel, varscan2
- FBXO6 | c.133C>T p.R45W | Missense Mutation (SNP) | VAF 40/71 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1382948502; called by muse, mutect2, varscan2
- FMR1 | c.1062dup p.H355Tfs*15 | Frame Shift Ins (INS) | VAF 85/170 reads (50%) | catalogued as rs781892436; called by mutect2, varscan2
- FOXD1 | c.155G>A p.R52Q | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated, low confidence (0.6); PolyPhen possibly damaging (0.602); catalogued as rs1196832423; called by muse, mutect2, varscan2
- FRY | c.6731A>G p.Q2244R | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs749421565; called by muse, mutect2, varscan2
- FSCB | c.440del p.P147Lfs*2 | Frame Shift Del (DEL) | VAF 18/47 reads (38%) | catalogued as COSV61219806; called by mutect2, pindel, varscan2
- FZD3 | c.1420C>T p.R474C | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs930901306; called by muse, mutect2, varscan2
- GAK | c.1262C>T p.S421L | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1338096609; called by muse, mutect2, varscan2
- GALNT17 | c.859C>T p.R287W | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs775779137, COSV61150179, COSV61154998; called by muse, mutect2, varscan2
- GAREM1 | c.2462G>A p.R821Q (on ENST00000269209 / NM_001242409.2; = p.R820Q on NM_022751.3) | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs756156267; called by muse, mutect2, varscan2
- GAREM1 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs143393429; called by muse, mutect2, varscan2
- GCK | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM096815; called by muse, mutect2, varscan2
- GDF6 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1293581615, COSV99748428; called by muse, mutect2, varscan2
- GLI2 | c.811G>A p.G271S | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.787); catalogued as rs144406619, COSV58052836; called by muse, mutect2, varscan2
- GLYR1 | c.1140del p.R381Afs*20 | Frame Shift Del (DEL) | VAF 8/56 reads (14%) | catalogued as rs749150409; called by mutect2, varscan2
- GNL3L | c.1568G>A p.R523H | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.8); catalogued as rs765688092, COSV100328493; called by muse, mutect2, varscan2
- GNPTG | c.632C>T p.T211I | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT tolerated (0.12); PolyPhen benign (0.11); catalogued as rs925124634; called by muse, mutect2, varscan2
- GOLGB1 | c.6889C>T p.R2297C | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as rs371237579; called by muse, mutect2, varscan2
- GPC2 | c.1047del p.D350Tfs*24 | Frame Shift Del (DEL) | VAF 9/27 reads (33%) | catalogued as rs748011069, COSV52786506; called by mutect2, pindel, varscan2
- GRHL2 | c.1697C>T p.A566V | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs768421169, COSV52550757; called by muse, mutect2, varscan2
- GUK1 | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs752446312, COSV57158150; called by muse, mutect2, varscan2
- GXYLT1 | c.668del p.L223Yfs*11 | Frame Shift Del (DEL) | VAF 21/58 reads (36%) | catalogued as rs750293240, COSV55140417; called by mutect2, pindel, varscan2
- HAPLN1 | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.35); PolyPhen benign (0.063); catalogued as rs746302136, COSV57148063; called by muse, mutect2, varscan2
- HCN4 | c.994C>T p.R332W | Missense Mutation (SNP) | VAF 40/81 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs141185786; called by muse, mutect2, varscan2
- HDC | c.355G>A p.V119I | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.098); catalogued as rs143849528; called by muse, mutect2, varscan2
- HDLBP | c.1207G>T p.E403* | Nonsense Mutation (SNP) | VAF 11/55 reads (20%) | catalogued as COSV60501233; called by muse, mutect2, varscan2
- HINFP | c.964A>G p.S322G | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as rs1305752309; called by muse, mutect2
- HOXB13 | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); catalogued as COSV51705295; called by muse, mutect2, varscan2
- HPS4 | c.1867A>G p.T623A | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT tolerated (0.59); PolyPhen benign (0.015); catalogued as rs1366471629; called by muse, mutect2, varscan2
- HSD17B11 | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs562443434; called by muse, mutect2, varscan2
- HTR3A | c.776T>C p.M259T | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.232); catalogued as rs776946829, COSV55471536; called by muse, mutect2
- IBSP | c.814G>A p.D272N | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.039); catalogued as rs577019057, COSV56895334; called by muse, mutect2, varscan2
- IL1R2 | c.589G>A p.V197M | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as rs772327590; called by muse, mutect2, varscan2
- INO80E | c.633del p.T212Rfs*3 | Frame Shift Del (DEL) | VAF 14/26 reads (54%) | catalogued as rs759306300, COSV58752155, COSV58752733; called by mutect2, varscan2
- INPP4A | c.781C>T p.Q261* | Nonsense Mutation (SNP) | VAF 11/27 reads (41%) | catalogued as COSV104380126; called by muse, mutect2, varscan2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 25/37 reads (68%) | catalogued as rs760925109; called by mutect2, pindel, varscan2
- IPO9 | c.1423C>T p.H475Y | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.036); catalogued as COSV64233855; called by muse, mutect2, varscan2
- IRF2BP1 | c.1745G>A p.R582Q | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); catalogued as COSV56193342; called by muse, mutect2
- IRX1 | c.1409C>T p.T470M | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs369886565, COSV57358201; called by muse, mutect2, varscan2
- ITGA2B | c.2517G>T p.Q839H | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.15); catalogued as COSV52234771; called by muse, mutect2, varscan2
- ITGA5 | c.1900C>T p.R634W | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1478270820; called by muse, mutect2, varscan2
- ITGB1BP2 | c.816+1del | Frame Shift Del (DEL) | VAF 24/69 reads (35%) | catalogued as rs767594769; called by mutect2, pindel, varscan2
- JCAD | c.1680G>T p.K560N | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as COSV64760678; called by muse, mutect2, varscan2
- JPH4 | c.1777G>A p.A593T | Missense Mutation (SNP) | VAF 61/128 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs1331354546; called by muse, mutect2, varscan2
- KCNJ14 | c.746C>T p.P249L | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.645); catalogued as rs1466110902; called by muse, mutect2, varscan2
- KCNN2 | c.989G>A p.R330Q (on ENST00000264773; = p.R542Q on NM_021614.4) | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs760430454; called by muse, mutect2, varscan2
- KCNN3 | c.173C>T p.S58L | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs1437869897; called by muse, varscan2
- KCTD10 | c.146C>T p.T49M | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV57327328; called by muse, mutect2
- KCTD15 | c.134T>C p.I45T | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.177); catalogued as COSV52290326; called by muse, mutect2
- KCTD8 | c.1082A>G p.D361G | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as COSV63585495; called by muse, mutect2, varscan2
- KDM4B | c.923C>T p.T308M | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as rs1568303558; called by muse, mutect2, varscan2
- KDM6B | c.1798G>A p.V600I | Missense Mutation (SNP) | VAF 54/128 reads (42%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as rs1480323634; called by muse, mutect2, varscan2
- KIF23 | c.1349C>T p.T450M | Missense Mutation (SNP) | VAF 57/110 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.104); catalogued as rs747785361, COSV52978566; called by muse, mutect2, varscan2
- KIF26B | c.3155C>T p.S1052F | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.467); catalogued as COSV63637791; called by muse, mutect2
- KIF26B | c.3692T>C p.I1231T | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.524); catalogued as COSV63645114; called by muse, mutect2, varscan2
- KIF2B | c.1627T>A p.L543I | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.074); catalogued as rs1470863139, COSV52132480; called by muse, mutect2, varscan2
- KIFC3 | c.1724C>T p.A575V | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs540121396; called by muse, mutect2, varscan2
- KIRREL3 | c.216del p.E73Nfs*30 | Frame Shift Del (DEL) | VAF 32/84 reads (38%) | catalogued as COSV101585710; called by mutect2, pindel, varscan2
- KLHL17 | c.1381G>A p.G461R | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.847); catalogued as rs1207032932, COSV58533193; called by muse, mutect2, varscan2
- KRT86 | c.115C>T p.R39C | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.191); catalogued as rs764149570; called by mutect2, varscan2
- KSR2 | c.1606del p.L536Sfs*61 | Frame Shift Del (DEL) | VAF 8/31 reads (26%) | catalogued as rs770565486; called by mutect2, pindel, varscan2
- LARP7 | c.*9del | Frame Shift Del (DEL) | VAF 44/84 reads (52%) | catalogued as rs746633076; called by mutect2, varscan2
- LBR | c.1238G>A p.R413H | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.041); catalogued as rs534522882, COSV55291392; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LCT | c.1865G>A p.R622H | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.212); catalogued as rs758609978, COSV99930246; called by muse, mutect2, varscan2
- LDB3 | c.1084A>G p.R362G | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs1341773470; called by muse, mutect2
- LENG8 | c.1430C>T p.A477V | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs778199336, COSV58730953; called by muse, mutect2, varscan2
- LILRB1 | c.365del p.P122Hfs*33 (on ENST00000427581; = p.P86Hfs*33 on NM_006669.6) | Frame Shift Del (DEL) | VAF 21/232 reads (9%) | catalogued as COSV61115655; called by mutect2, pindel
- LMAN1 | c.912del p.E305Rfs*22 | Frame Shift Del (DEL) | VAF 18/41 reads (44%) | catalogued as rs746845401, CD099553; called by mutect2, varscan2
- LMO7 | c.1597C>T p.R533* (on ENST00000357063; = p.R263* on NM_015842.2 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 17/31 reads (55%) | catalogued as rs771270683, COSV58543125; called by muse, mutect2, varscan2
- MAG | c.262C>T p.R88C | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1289188530; called by muse, mutect2
- MAMLD1 | c.20G>A p.R7Q | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.986); catalogued as rs1557404746, COSV53371827; called by muse, mutect2, varscan2
- MAP1A | c.1814G>A p.S605N | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.109); catalogued as rs1257300761; called by muse, mutect2
- MBTPS1 | c.387A>C p.Q129H | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.247); catalogued as COSV58570442; called by muse, mutect2, varscan2
- MEGF11 | c.1303G>A p.V435I | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs141697214; called by muse, mutect2, varscan2
- MIS18BP1 | c.1139del p.N380Ifs*3 | Frame Shift Del (DEL) | VAF 34/72 reads (47%) | catalogued as rs751180035; called by mutect2, varscan2
- MTG2 | c.1138C>T p.Q380* | Nonsense Mutation (SNP) | VAF 18/36 reads (50%) | catalogued as rs1355085520; called by muse, mutect2, varscan2
- MTRR | c.349C>T p.R117W (on ENST00000264668; = p.R90W on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.061); catalogued as rs773984668, COSV52945478; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MUC4 | c.13222C>T p.R4408W (on ENST00000463781 / NM_018406.7; = p.R172W on NM_004532.6) | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); catalogued as rs759984110, COSV57769600; called by muse, mutect2, varscan2
- MYH2 | c.5579C>T p.T1860M | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs148724880; called by muse, mutect2, varscan2
- MYH8 | c.1305C>A p.Y435* | Nonsense Mutation (SNP) | VAF 41/119 reads (34%) | catalogued as COSV67963329, COSV67974187; called by muse, mutect2, varscan2
- MYOM3 | c.1787G>A p.R596Q | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated (0.91); PolyPhen benign (0.034); catalogued as rs1342815697, COSV100293249, COSV58390559; called by muse, mutect2, varscan2
- MYPOP | c.1109del p.P370Qfs*36 | Frame Shift Del (DEL) | VAF 10/17 reads (59%) | catalogued as rs746192154; called by mutect2, varscan2
- NAIF1 | c.550G>A p.V184M | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as rs752082521; called by muse, varscan2
- NCKAP5L | c.3932del p.P1311Qfs*57 | Frame Shift Del (DEL) | VAF 10/98 reads (10%) | catalogued as rs750891910; called by mutect2, pindel
- NCOA6 | c.1688C>T p.A563V | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs1298121586; called by muse, varscan2
- NEB | c.13837G>A p.V4613I | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.983); catalogued as rs764044045; called by muse, mutect2, varscan2
- NEURL4 | c.1540G>A p.A514T | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs376345187; called by muse, mutect2, varscan2
- NOLC1 | c.840del p.K280Nfs*3 | Frame Shift Del (DEL) | VAF 12/44 reads (27%) | catalogued as rs759637346; called by mutect2, varscan2
- NOS3 | c.1114C>T p.R372C | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs41508746; called by muse, mutect2, varscan2
- NRAP | c.1283G>A p.R428H (on ENST00000359988 / NM_001322945.2; = p.R393H on NM_006175.4) | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.933); catalogued as rs757025097, COSV63490954; called by muse, mutect2, varscan2
- NXPH1 | c.169C>T p.R57* | Nonsense Mutation (SNP) | VAF 17/25 reads (68%) | catalogued as COSV99068060; called by muse, mutect2, varscan2
- NYNRIN | c.455G>C p.R152P | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs757243958; called by muse, mutect2, varscan2
- OBSCN | c.13342del p.Q4448Rfs*92 | Frame Shift Del (DEL) | VAF 11/39 reads (28%) | catalogued as COSV52816548; called by mutect2, pindel, varscan2
- OLFML2A | c.921C>T p.D307= | Splice Region (SNP) | VAF 12/103 reads (12%) | catalogued as COSV56585450; called by muse, mutect2, varscan2
- OR4N2 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1350071379; called by muse, mutect2, varscan2
- OSCAR | c.170G>A p.C57Y | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757218082; called by muse, mutect2
- OTOP2 | c.1346C>T p.T449I | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as COSV58882281; called by muse, mutect2
- P2RY4 | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.517); catalogued as rs775969220, COSV65736719; called by muse, mutect2, varscan2
- P4HB | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1309280616, COSV100515796; called by muse, mutect2, varscan2
- PARP1 | c.868G>A p.G290S | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1045389347, COSV104422538; called by muse, mutect2, varscan2
- PAXIP1 | c.300del p.F100Lfs*31 | Frame Shift Del (DEL) | VAF 26/88 reads (30%) | catalogued as rs753190856; called by mutect2, varscan2
- PAXX | c.536G>A p.R179Q | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.695); catalogued as rs558231652, COSV100860430, COSV65406939; called by muse, mutect2, varscan2
- PCDHA3 | c.1288G>A p.G430R | Missense Mutation (SNP) | VAF 56/116 reads (48%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.308); catalogued as rs782408810; called by muse, mutect2, varscan2
- PCDHGB7 | c.1495C>T p.R499* | Nonsense Mutation (SNP) | VAF 19/35 reads (54%) | catalogued as COSV53926580; called by muse, mutect2, varscan2
- PDIA6 | c.1043C>T p.A348V | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as rs141560971; called by muse, mutect2, varscan2
- PDS5B | c.4169del p.N1390Mfs*4 | Frame Shift Del (DEL) | VAF 18/25 reads (72%) | catalogued as rs759495724; called by mutect2, varscan2
- PFKP | c.1785del p.L596Sfs*27 | Frame Shift Del (DEL) | VAF 31/84 reads (37%) | catalogued as rs747416036; called by mutect2, pindel, varscan2
- PHACTR4 | c.160del p.S54Vfs*12 (on ENST00000373839 / NM_001350159.2; = p.S64Vfs*12 on NM_023923.4) | Frame Shift Del (DEL) | VAF 35/74 reads (47%) | catalogued as rs761437290, COSV65783432; called by mutect2, varscan2
- PHF2 | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.014); catalogued as rs756847481, COSV63679268; called by muse, mutect2, varscan2
- PIDD1 | c.2179G>A p.A727T | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs141820504; called by muse, varscan2
- PIK3CG | c.1543T>C p.S515P | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.356); catalogued as COSV63250061; called by muse, mutect2, varscan2
- PIWIL2 | c.67C>T p.R23W | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.635); catalogued as rs375849565, COSV100769544; called by muse, mutect2, varscan2
- PLA1A | c.41del p.G14Afs*53 | Frame Shift Del (DEL) | VAF 20/48 reads (42%) | catalogued as rs749203497; called by mutect2, pindel, varscan2
- PLEC | c.13000C>T p.R4334C (on ENST00000322810 / NM_201380.4; = p.R4224C on NM_000445.5) | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs568673535; ClinVar: uncertain significance; called by muse, mutect2
- PLXNA2 | c.2422C>T p.R808W | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs373107594; called by muse, mutect2, varscan2
- PLXNA2 | c.1477C>T p.R493C | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs750345311, COSV65437952; called by muse, mutect2, varscan2
- PLXNB1 | c.3728G>A p.R1243H | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs571547770; called by muse, mutect2, varscan2
- PLXNB1 | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs765174256; called by muse, mutect2, varscan2
- PMEPA1 | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV55695611; called by muse, mutect2
- PPFIA3 | c.943G>A p.A315T | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV100494689, COSV61953832; called by muse, mutect2
- PPP1R12A | c.1619del p.N540Ifs*23 | Frame Shift Del (DEL) | VAF 18/44 reads (41%) | catalogued as rs776166170; called by mutect2, varscan2
- PPP6R1 | c.1334C>T p.T445M | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as rs569114548; called by muse, mutect2, varscan2
- PPP6R2 | c.2561dup p.L855Afs*18 (on ENST00000216061 / NM_001365836.1; = p.L821Afs*18 on NM_014678.5 and 4 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 15/67 reads (22%) | catalogued as rs777185590; called by mutect2, varscan2
- PPRC1 | c.4382del p.P1461Hfs*79 | Frame Shift Del (DEL) | VAF 31/82 reads (38%) | catalogued as COSV53386648; called by mutect2, pindel, varscan2
- PRR14 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.177); catalogued as rs749081660, COSV54910979; called by muse, mutect2, varscan2
- PSD | c.750del p.S251Afs*43 | Frame Shift Del (DEL) | VAF 40/101 reads (40%) | catalogued as rs761494960; called by mutect2, pindel, varscan2
- PXDNL | c.2869G>A p.G957R | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755663197, COSV62478360; called by muse, mutect2, varscan2
- RAB11FIP5 | c.1906C>T p.R636W | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1202090475, COSV99242383; called by muse, mutect2, varscan2
- RAD50 | c.3748G>A p.V1250I | Missense Mutation (SNP) | VAF 44/90 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as rs1200638952; called by muse, mutect2, varscan2
- RBBP8NL | c.1840C>T p.R614W | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.672); catalogued as rs150734075; called by muse, mutect2, varscan2
- RBM45 | c.1149del p.A384Lfs*7 (on ENST00000616198 / NM_001365579.1; = p.A382Lfs*7 on NM_152945.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 37/72 reads (51%) | catalogued as rs749563266; called by mutect2, varscan2
- RBP1 | c.100G>A p.A34T (on ENST00000619087 / NM_001365940.2; = p.A96T on NM_002899.5) | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV99218647; called by muse, mutect2, varscan2
- RBP7 | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.018); catalogued as rs775981100, COSV53813069; called by muse, varscan2
- RGR | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs780231448, COSV100812895; called by muse, mutect2, varscan2
- RIMBP2 | c.1822C>T p.P608S | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as COSV55482973; called by muse, mutect2
- RIMBP2 | c.1463C>G p.A488G | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV99900960; called by muse, mutect2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 49/74 reads (66%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 11/31 reads (35%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RYK | c.1036C>T p.R346C (on ENST00000620660 / NM_001005861.2; = p.R343C on NM_002958.4) | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.274); catalogued as rs752906721, COSV56061959; called by mutect2, varscan2
- SALL2 | c.1780C>T p.Q594* | Nonsense Mutation (SNP) | VAF 20/41 reads (49%) | catalogued as rs1398651466; called by muse, mutect2, varscan2
- SART3 | c.793G>A p.V265I (on ENST00000228284; = p.V247I on NM_014706.4) | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV57206403; called by muse, mutect2
- SEC16A | c.6197del p.P2066Qfs*76 | Frame Shift Del (DEL) | VAF 23/77 reads (30%) | catalogued as COSV99256980; called by mutect2, pindel, varscan2
- SET | c.787G>A p.E263K (on ENST00000372692 / NM_001374326.1; = p.E250K on NM_003011.4) | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.084); catalogued as rs1013644374, COSV59002635; called by muse, mutect2, varscan2
- SETMAR | c.1714C>T p.R572C | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.042); catalogued as rs755420652; called by muse, mutect2, varscan2
- SFPQ | c.1219C>A p.R407S | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV61758592; called by muse, mutect2, varscan2
- SFSWAP | c.2419C>T p.R807W | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.99); catalogued as rs777239707; called by muse, mutect2, varscan2
- SGMS1 | c.265G>A p.V89I | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs760832061; called by muse, mutect2, varscan2
- SH2D3A | c.208C>T p.R70W | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs375700170; called by muse, mutect2, varscan2
- SH3PXD2A | c.2587G>A p.A863T (on ENST00000369774 / NM_001365079.1; = p.A835T on NM_014631.2) | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as rs766798828, COSV60116246; called by muse, mutect2, varscan2
- SHANK3 | c.3370G>A p.V1124M | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.884); catalogued as COSV53190269; called by muse, mutect2, varscan2
- SIN3B | c.2755C>T p.R919W | Missense Mutation (SNP) | VAF 76/152 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as rs753206215; called by muse, mutect2, varscan2
- SKOR1 | c.297C>A p.C99* | Nonsense Mutation (SNP) | VAF 15/31 reads (48%) | catalogued as COSV58249072; called by muse, mutect2, varscan2
- SLC12A4 | c.500C>T p.T167M | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1478090109; called by muse, mutect2, varscan2
- SLC12A7 | c.2623C>T p.R875W | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as rs150458053; called by muse, mutect2
- SLC1A7 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.052); catalogued as rs776189525, COSV101019721; called by mutect2, varscan2
- SLC20A1 | c.1909C>T p.R637W | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762352158, COSV55612330; called by muse, mutect2, varscan2
- SLC2A14 | c.740C>T p.T247M | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.108); catalogued as rs778496220, COSV61586827; called by muse, mutect2, varscan2
- SLC9A3 | c.1756C>A p.L586I | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.037); catalogued as rs1316075569; called by muse, mutect2, varscan2
- SMOX | c.1247C>T p.P416L | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs144794871; called by muse, mutect2
- SNAPIN | c.392del p.P131Lfs*9 | Frame Shift Del (DEL) | VAF 46/136 reads (34%) | catalogued as rs1278771008; called by mutect2, varscan2
- SNRNP70 | c.715C>T p.R239W | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs1381408145; called by muse, mutect2
- SNX20 | c.473G>A p.R158Q | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as COSV56057374; called by muse, mutect2, varscan2
- SORCS1 | c.461G>A p.R154Q | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.194); catalogued as COSV53895310; called by muse, mutect2, varscan2
- SOX9 | c.184_186del p.K62del | In Frame Del (DEL) | VAF 56/118 reads (47%) | catalogued as rs778226772; called by pindel, varscan2
- SPATA21 | c.596C>T p.P199L | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs758312284; called by mutect2, varscan2
- SPATC1 | c.790del p.Q264Sfs*152 | Frame Shift Del (DEL) | VAF 24/55 reads (44%) | catalogued as rs782200741; called by mutect2, pindel, varscan2
- SPECC1 | c.908del p.N303Tfs*63 | Frame Shift Del (DEL) | VAF 10/22 reads (45%) | catalogued as COSV54965656; called by mutect2, varscan2
- SPTBN4 | c.1583G>A p.R528Q | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.878); catalogued as rs145007629; called by muse, mutect2, varscan2
- SRFBP1 | c.1273del p.I425Lfs*7 | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | catalogued as rs746594147, COSV59581931; called by mutect2, pindel, varscan2
- SSTR1 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.59); PolyPhen benign (0.069); catalogued as COSV57456495; called by muse, mutect2, varscan2
- SSTR1 | c.725G>A p.C242Y | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57458092; called by muse, mutect2, varscan2
- ST3GAL4 | c.191G>A p.R64Q (on ENST00000392669 / NM_001254758.1; = p.R60Q on NM_006278.3) | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT tolerated (0.12); PolyPhen benign (0.104); catalogued as rs371057579; called by muse, mutect2, varscan2
- STARD13 | c.2846C>T p.P949L (on ENST00000336934 / NM_001243476.3; = p.P831L on NM_052851.3) | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as rs754302022, COSV55236718; called by muse, mutect2, varscan2
- STAU2 | c.894C>T p.A298= (on ENST00000524300 / NM_001164380.2; = p.A266= on NM_014393.2) | Splice Region (SNP) | VAF 56/135 reads (41%) | catalogued as rs371435229; called by muse, mutect2, varscan2
- SUGP2 | c.1430G>A p.R477Q | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.375); catalogued as rs763221092; called by muse, mutect2, varscan2
- SUOX | c.890G>A p.R297Q | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as rs764275182; ClinVar: uncertain significance; called by muse, varscan2
- SYTL3 | c.1286G>A p.R429H (on ENST00000611299 / NM_001242394.1; = p.R361H on NM_001009991.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/73 reads (55%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs141770650; called by muse, mutect2, varscan2
- SZT2 | c.5681G>A p.R1894Q (on ENST00000634258 / NM_001365999.1; = p.R1837Q on NM_015284.4) | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT tolerated (0.25); PolyPhen benign (0.096); catalogued as rs144742948; called by muse, mutect2, varscan2
- TCERG1 | c.2870del p.K957Rfs*17 | Frame Shift Del (DEL) | VAF 23/46 reads (50%) | catalogued as rs758822980; called by mutect2, varscan2
- TDG | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 67/138 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.072); catalogued as rs375015053, COSV57167611; called by muse, mutect2, varscan2
- TET2 | c.1742G>A p.R581H | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs531508917; called by muse, mutect2, varscan2
- TM9SF3 | c.214del p.S72Vfs*31 | Frame Shift Del (DEL) | VAF 48/100 reads (48%) | catalogued as rs760930120; called by mutect2, varscan2
- TMEM102 | c.397C>G p.L133V | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated (0.32); PolyPhen benign (0.037); catalogued as rs781113230; called by muse, mutect2, varscan2
- TOP3B | c.1601G>A p.R534Q | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.426); catalogued as rs752975410, COSV100592271; called by muse, mutect2, varscan2
- TRAV38-1 | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.652); catalogued as rs765543519; called by muse, mutect2, varscan2
- TRIM51 | c.884G>A p.R295K | Missense Mutation (SNP) | VAF 4/69 reads (6%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as COSV55264767, COSV55271903; called by muse, mutect2
- TRIM56 | c.1630G>A p.V544M | Missense Mutation (SNP) | VAF 53/103 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs192903356; called by muse, mutect2, varscan2
- TRMT9B | c.466G>A p.V156M | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1414766630; called by muse, mutect2, varscan2
- TRPV6 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs777414117, COSV63890965; called by muse, mutect2, varscan2
- TRUB1 | c.1018_1019del p.K340Efs*4 | Frame Shift Del (DEL) | VAF 6/21 reads (29%) | catalogued as rs770128532; called by mutect2, pindel, varscan2
- TTBK2 | c.959G>A p.R320H | Missense Mutation (SNP) | VAF 43/77 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1357204824, COSV51158551; called by muse, mutect2, varscan2
- TTK | c.2571del p.K857Nfs*36 | Frame Shift Del (DEL) | VAF 6/12 reads (50%) | catalogued as rs768996038, COSV57882295; called by mutect2, varscan2
- TVP23A | c.420del p.F140Lfs*7 | Frame Shift Del (DEL) | VAF 12/56 reads (21%) | catalogued as rs760251146; called by mutect2, varscan2
- UGT2B7 | c.1097C>T p.P366L | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as COSV59442435; called by muse, mutect2, varscan2
- UHRF1BP1 | c.205C>T p.R69W | Missense Mutation (SNP) | VAF 38/72 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs754882631, COSV99512113; called by muse, mutect2, varscan2
- UNC79 | c.7823G>A p.R2608Q (on ENST00000393151 / NM_001346218.2; = p.R2431Q on NM_020818.5) | Missense Mutation (SNP) | VAF 31/54 reads (57%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.448); catalogued as rs368890148; called by muse, mutect2, varscan2
- UPF1 | c.763C>T p.R255C | Missense Mutation (SNP) | VAF 52/101 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); catalogued as COSV53202527; called by muse, mutect2, varscan2
- USP29 | c.1068dup p.V357Sfs*16 | Frame Shift Ins (INS) | VAF 9/35 reads (26%) | catalogued as rs779367461; called by mutect2, pindel, varscan2
- USP35 | c.1962del p.T655Pfs*23 | Frame Shift Del (DEL) | VAF 34/66 reads (52%) | catalogued as rs764735138; called by mutect2, varscan2
- UXT | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.125); catalogued as rs1457961356, COSV60039202; called by muse, mutect2, varscan2
- VWF | c.6886T>C p.C2296R | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99779029; called by muse, mutect2, varscan2
- WDR24 | c.391C>T p.R131C (on ENST00000248142; = p.R69C on NM_032259.4) | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV50198235; called by muse, mutect2, varscan2
- WDR45 | c.20G>A p.R7Q | Missense Mutation (SNP) | VAF 46/99 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs782671518, COSV59876949; ClinVar: benign; called by muse, mutect2, varscan2
- WDR47 | c.241del p.R81Gfs*7 | Frame Shift Del (DEL) | VAF 16/39 reads (41%) | catalogued as rs1557951659, COSV63058584; called by mutect2, pindel, varscan2
- WDR55 | c.1022del p.K341Rfs*8 | Frame Shift Del (DEL) | VAF 14/26 reads (54%) | catalogued as rs746919573; called by mutect2, varscan2
- WFIKKN1 | c.121C>A p.L41M | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99938022; called by muse, mutect2, varscan2
- WRAP53 | c.1565del p.A522Gfs*26 | Frame Shift Del (DEL) | VAF 23/59 reads (39%) | catalogued as rs373064567, COSV56832921, COSV56833408; called by mutect2, pindel, varscan2
- ZACN | c.756del p.L253Cfs*10 | Frame Shift Del (DEL) | VAF 27/62 reads (44%) | catalogued as rs746294699; called by mutect2, pindel, varscan2
- ZC3H18 | c.2037del p.R680Gfs*5 | Frame Shift Del (DEL) | VAF 12/31 reads (39%) | catalogued as rs751577786; called by mutect2, varscan2
- ZC3H4 | c.2335G>C p.E779Q | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs756950439, COSV53410194; called by muse, mutect2, varscan2
- ZMYND8 | c.1904del p.K635Sfs*14 (on ENST00000311275 / NM_001363741.2; = p.K655Sfs*14 on NM_012408.6 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 14/37 reads (38%) | catalogued as rs776813452; called by mutect2, varscan2
- ZNF257 | c.16A>G p.I6V | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV71309816; called by muse, mutect2, varscan2
- ZNF263 | c.1106C>T p.P369L | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as rs541895788, COSV54596555, COSV99526813; called by muse, mutect2, varscan2
- ZNF292 | c.6145del p.S2049Vfs*11 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | catalogued as rs764995318; called by mutect2, varscan2
- ZNF3 | c.155C>T p.T52I | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as rs938818473; called by muse, mutect2, varscan2
- ZNF311 | c.1177G>A p.G393R | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.327); catalogued as rs765712189, COSV101014142, COSV65853519; called by muse, mutect2, varscan2
- ZNF335 | c.683C>T p.P228L | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs775817481, COSV59817273; called by muse, mutect2, varscan2
- ZNF341 | c.863G>A p.G288D | Missense Mutation (SNP) | VAF 43/172 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as rs144685026; called by muse, mutect2, varscan2
- ZNF551 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.3); PolyPhen benign (0.081); catalogued as COSV99989946; called by muse, mutect2, varscan2
- ZNF596 | c.1181A>G p.H394R | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT tolerated (0.08); PolyPhen benign (0.392); catalogued as rs962957390; called by muse, mutect2, varscan2
- ZNF614 | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs778179613; called by muse, varscan2
- ZNF648 | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs377557581; called by muse, mutect2
- ZNF708 | c.1405del p.I469Ffs*28 | Frame Shift Del (DEL) | VAF 13/50 reads (26%) | catalogued as rs769330978; called by mutect2, pindel, varscan2
- ZNF71 | c.1382C>T p.T461M | Missense Mutation (SNP) | VAF 46/85 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV60150006; called by muse, mutect2, varscan2
- ZRANB1 | c.*9del | Frame Shift Del (DEL) | VAF 8/27 reads (30%) | catalogued as rs535580590; called by mutect2, varscan2
- AC098582.1 | c.2987C>T p.S996F | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- AHDC1 | c.1937T>G p.V646G | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); called by muse, mutect2
- AKAP12 | c.2844del p.T949Rfs*23 | Frame Shift Del (DEL) | VAF 21/50 reads (42%) | called by mutect2, pindel, varscan2
- AKAP9 | c.6289dup p.M2097Nfs*7 (on ENST00000359028; = p.M2065Nfs*7 on NM_005751.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 16/42 reads (38%) | called by mutect2, pindel, varscan2
- ALMS1 | c.9717A>C p.K3239N | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ALPK2 | c.5629+2T>C p.X1877_splice | Splice Site (SNP) | VAF 7/61 reads (11%) | called by muse, mutect2, varscan2
- ALPK2 | c.2798G>A p.S933N | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- AMBRA1 | c.332T>A p.I111N | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- AMY2A | c.205C>A p.P69T | Missense Mutation (SNP) | VAF 100/331 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- ANKMY2 | c.898G>A p.A300T | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- ANKRD12 | c.1986del p.E663Kfs*49 | Frame Shift Del (DEL) | VAF 27/67 reads (40%) | called by mutect2, pindel, varscan2
- ARF1 | c.335C>T p.A112V | Missense Mutation (SNP) | VAF 39/156 reads (25%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARFGAP3 | c.456del p.F152Lfs*9 | Frame Shift Del (DEL) | VAF 7/31 reads (23%) | called by mutect2, pindel, varscan2
- ARHGAP21 | c.1653A>T p.K551N | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- ARHGAP32 | c.48C>A p.F16L | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.086); called by muse, varscan2
- ARID1A | c.2272del p.Q758Rfs*75 | Frame Shift Del (DEL) | VAF 50/114 reads (44%) | called by mutect2, pindel, varscan2
- ART3 | c.277A>G p.N93D | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ARVCF | c.1403T>C p.L468P | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATF7IP | c.3811T>C p.*1271Qext*66 | Nonstop Mutation (SNP) | VAF 40/77 reads (52%) | called by muse, mutect2, varscan2
- ATG2B | c.4874G>A p.C1625Y | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- ATN1 | c.2675C>A p.P892H | Missense Mutation (SNP) | VAF 37/61 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP13A5 | c.1162del p.R388Gfs*3 | Frame Shift Del (DEL) | VAF 10/40 reads (25%) | called by mutect2, pindel, varscan2
- ATP6V0D1 | c.205G>A p.V69I | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT tolerated (0.53); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- ATP8B2 | c.2288G>A p.G763D (on ENST00000672630; = p.G730D on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- BASP1 | c.207G>T p.K69N | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- BAZ1B | c.4450T>C p.*1484Qext*35 | Nonstop Mutation (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2, varscan2
- BCAT2 | c.605C>A p.P202H | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- BNC2 | c.2462C>T p.S821F | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, varscan2
- BTBD7 | c.2303del p.P768Qfs*53 | Frame Shift Del (DEL) | VAF 26/70 reads (37%) | called by mutect2, pindel, varscan2
- BTBD8 | c.262A>T p.I88F | Missense Mutation (SNP) | VAF 54/142 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C15orf39 | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- C20orf85 | c.190A>C p.K64Q | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- CACNA1D | c.1720dup p.M574Nfs*18 (on ENST00000350061 / NM_001128840.3; = p.M594Nfs*18 on NM_000720.4) | Frame Shift Ins (INS) | VAF 16/51 reads (31%) | called by mutect2, pindel, varscan2
- CACNA1S | c.2392G>A p.A798T | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- CAPS2 | c.1470G>A p.W490* | Nonsense Mutation (SNP) | VAF 20/35 reads (57%) | called by muse, mutect2, varscan2
- CASQ1 | c.894G>T p.E298D | Missense Mutation (SNP) | VAF 35/180 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- CCNJL | c.1193C>T p.S398F | Missense Mutation (SNP) | VAF 41/80 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- CD101 | c.604_605del p.S202Qfs*19 | Frame Shift Del (DEL) | VAF 20/68 reads (29%) | called by pindel, varscan2
- CD1E | c.993del p.K331Nfs*47 | Frame Shift Del (DEL) | VAF 25/127 reads (20%) | called by mutect2, pindel, varscan2
- CDK5RAP2 | c.1413del p.K471Nfs*8 | Frame Shift Del (DEL) | VAF 17/47 reads (36%) | called by mutect2, pindel, varscan2
- CEP192 | c.5168A>C p.E1723A | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- CERS1 | c.992T>C p.L331P | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2
- CHD3 | c.1618del p.R540Vfs*16 | Frame Shift Del (DEL) | VAF 28/69 reads (41%) | called by mutect2, pindel, varscan2
- CLASRP | c.284del p.P95Lfs*81 | Frame Shift Del (DEL) | VAF 29/70 reads (41%) | called by mutect2, varscan2
- CMAS | c.610C>T p.R204* | Nonsense Mutation (SNP) | VAF 40/89 reads (45%) | called by muse, mutect2, varscan2
- CMC2 | c.81T>G p.N27K | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CNOT4 | c.95C>T p.T32I | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- COPA | c.3616-2A>G p.X1206_splice | Splice Site (SNP) | VAF 15/115 reads (13%) | called by muse, mutect2, varscan2
- COQ3 | c.704del p.L235Yfs*8 | Frame Shift Del (DEL) | VAF 5/46 reads (11%) | called by mutect2, pindel, varscan2
- COX7A2 | c.114+1G>A p.X38_splice | Splice Site (SNP) | VAF 21/53 reads (40%) | called by muse, mutect2, varscan2
- CPA3 | c.707del p.N236Ifs*59 | Frame Shift Del (DEL) | VAF 29/69 reads (42%) | called by mutect2, pindel, varscan2
- CR1 | c.347A>G p.H116R | Missense Mutation (SNP) | VAF 29/153 reads (19%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- CSGALNACT1 | c.1357C>T p.L453F | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSMD3 | c.2698del p.S900Qfs*6 (on ENST00000297405 / NM_001363185.1; = p.S796Qfs*6 on NM_052900.3) | Frame Shift Del (DEL) | VAF 6/51 reads (12%) | called by mutect2, pindel, varscan2
- CUBN | c.7490T>C p.L2497P | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CYP2A13 | c.264G>T p.K88N | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- DAG1 | c.1318G>A p.D440N | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- DDHD2 | c.1661G>T p.G554V | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.18); called by muse, varscan2
- DDX27 | c.304G>T p.A102S | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT tolerated (0.55); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DDX60 | c.3904T>C p.C1302R | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DLGAP5 | c.2515del p.S839Hfs*28 | Frame Shift Del (DEL) | VAF 31/143 reads (22%) | called by mutect2, pindel, varscan2
- DLX1 | c.400A>C p.I134L | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DMAP1 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- DNAH7 | c.10282G>A p.A3428T | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DOCK2 | c.5404_5406del p.K1802del | In Frame Del (DEL) | VAF 6/46 reads (13%) | called by pindel, varscan2
- DPH1 | c.800G>A p.R267H | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- DPH5 | c.777A>G p.I259M | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DPYSL5 | c.416C>T p.P139L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- DSCAML1 | c.3461del p.P1154Lfs*127 (on ENST00000321322; = p.P1094Lfs*127 on NM_020693.4) | Frame Shift Del (DEL) | VAF 34/65 reads (52%) | called by mutect2, pindel, varscan2
- DUOXA1 | c.458C>A p.P153H | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DUSP15 | c.451del p.T151Pfs*9 | Frame Shift Del (DEL) | VAF 19/74 reads (26%) | called by mutect2, pindel, varscan2
- DYRK1A | c.1463A>C p.N488T | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- EDEM2 | c.574A>G p.T192A | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- EGF | c.2515G>T p.G839* | Nonsense Mutation (SNP) | VAF 21/51 reads (41%) | called by muse, mutect2, varscan2
- EP400 | c.552del p.S185Pfs*129 | Frame Shift Del (DEL) | VAF 30/80 reads (38%) | called by mutect2, pindel, varscan2
- EPG5 | c.7643G>T p.R2548M | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); called by muse, mutect2, varscan2
- EPS15L1 | c.692del p.P231Hfs*37 | Frame Shift Del (DEL) | VAF 13/38 reads (34%) | called by mutect2, pindel, varscan2
- ERP44 | c.241A>G p.N81D | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ETV4 | c.839T>C p.L280P | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- FAF1 | c.1596_1597dup p.M533Rfs*26 | Frame Shift Ins (INS) | VAF 45/96 reads (47%) | called by mutect2, varscan2
- FAM155A | c.520dup p.Q174Pfs*54 | Frame Shift Ins (INS) | VAF 18/44 reads (41%) | called by mutect2, pindel, varscan2
- FAM189B | c.1532C>G p.T511S | Missense Mutation (SNP) | VAF 14/161 reads (9%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.931); called by muse, mutect2
- FAM20B | c.169G>A p.D57N | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0.005); called by muse, mutect2
- FAT3 | c.6872C>T p.T2291I | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- FBXL19 | c.674C>T p.T225I | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.425); called by muse, mutect2
- FBXO38 | c.1892_1893del p.E631Vfs*40 | Frame Shift Del (DEL) | VAF 14/36 reads (39%) | called by pindel, varscan2
- FBXW11 | c.1500del p.F500Lfs*16 | Frame Shift Del (DEL) | VAF 17/52 reads (33%) | called by mutect2, pindel, varscan2
- FLNB | c.2105G>A p.G702D | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FLT3 | c.2418+1G>A p.X806_splice | Splice Site (SNP) | VAF 17/74 reads (23%) | called by muse, mutect2, varscan2
- FOXD4L1 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 114/277 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FRY | c.2572A>G p.S858G | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.48); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GABRA2 | c.384del p.H129Tfs*7 | Frame Shift Del (DEL) | VAF 13/39 reads (33%) | called by mutect2, pindel, varscan2
- GABRB2 | c.20G>T p.R7M | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GALNT18 | c.936del p.K313Rfs*149 | Frame Shift Del (DEL) | VAF 6/53 reads (11%) | called by mutect2, pindel, varscan2
- GALNT7 | c.239T>C p.V80A | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.137); called by muse, mutect2
- GDI2 | c.754A>G p.N252D | Missense Mutation (SNP) | VAF 50/114 reads (44%) | SIFT tolerated (0.45); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- GLI2 | c.1850G>T p.S617I (on ENST00000361492 / NM_001374353.1; = p.S634I on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- GLI4 | c.98A>G p.Q33R | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, mutect2, varscan2
- GOLPH3L | c.812C>G p.A271G | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GPR37L1 | c.1249C>A p.L417I | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, varscan2
- GRAMD2B | c.145T>C p.S49P | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GRINA | c.23dup p.L8Ffs*119 | Frame Shift Ins (INS) | VAF 52/143 reads (36%) | called by mutect2, pindel, varscan2
- GRK4 | c.640G>A p.A214T (on ENST00000398052 / NM_182982.3; = p.A182T on NM_005307.3) | Missense Mutation (SNP) | VAF 38/69 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- GSE1 | c.3278del p.P1093Qfs*45 | Frame Shift Del (DEL) | VAF 40/103 reads (39%) | called by mutect2, pindel, varscan2
- GSN | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- H1-6 | c.253A>G p.K85E | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HAUS7 | c.361C>A p.P121T | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- HAUS8 | c.404C>A p.P135H | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.534); called by muse, mutect2, varscan2
- HDAC2 | c.154del p.M52Wfs*14 | Frame Shift Del (DEL) | VAF 13/32 reads (41%) | called by mutect2, pindel, varscan2
- HEMGN | c.544G>A p.V182I | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- HERC1 | c.5371A>G p.M1791V | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- HMBS | c.110G>A p.S37N | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- HNRNPUL2 | c.640T>G p.Y214D | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- IBTK | c.2372T>A p.L791H | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ICE1 | c.5131C>T p.P1711S | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ICE2 | c.2934A>C p.K978N | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IFT43 | c.56G>T p.R19M | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.195); called by muse, mutect2, varscan2
- IGDCC3 | c.1707del p.I570Sfs*23 | Frame Shift Del (DEL) | VAF 15/41 reads (37%) | called by mutect2, pindel, varscan2
- IKZF1 | c.1156C>T p.R386C | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- INPPL1 | c.1960_1962del p.E654del | In Frame Del (DEL) | VAF 34/62 reads (55%) | called by pindel, varscan2
- ITIH5 | c.94G>A p.G32R | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.481); called by muse, mutect2, varscan2
- ITSN1 | c.808C>T p.Q270* | Nonsense Mutation (SNP) | VAF 19/62 reads (31%) | called by muse, mutect2, varscan2
- JADE2 | c.191C>A p.P64Q | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- JTB | c.22C>A p.P8T | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KANSL3 | c.1927C>T p.R643* (on ENST00000666923 / NM_001349262.2; = p.R617* on NM_001115016.3) | Nonsense Mutation (SNP) | VAF 45/84 reads (54%) | called by muse, mutect2, varscan2
- KATNA1 | c.443G>A p.R148K | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, varscan2
- KCNB2 | c.2627del p.K876Rfs*38 | Frame Shift Del (DEL) | VAF 11/53 reads (21%) | called by mutect2, pindel, varscan2
- KCNH1 | c.522del p.G175Afs*51 | Frame Shift Del (DEL) | VAF 13/80 reads (16%) | called by mutect2, pindel, varscan2
- KCTD6 | c.692T>C p.L231P | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- KEL | c.1930A>G p.I644V | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- KIAA1614 | c.202del p.Q68Sfs*20 | Frame Shift Del (DEL) | VAF 24/133 reads (18%) | called by mutect2, varscan2
- KIF18B | c.337del p.A113Lfs*19 | Frame Shift Del (DEL) | VAF 14/79 reads (18%) | called by mutect2, pindel, varscan2
- KIF18B | c.292C>A p.L98I | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KIF21B | c.79T>G p.C27G | Missense Mutation (SNP) | VAF 31/183 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KIF5C | c.669del p.K223Nfs*43 | Frame Shift Del (DEL) | VAF 18/110 reads (16%) | called by mutect2, varscan2
- KLHL36 | c.1034del p.G345Afs*39 | Frame Shift Del (DEL) | VAF 28/117 reads (24%) | called by mutect2, pindel, varscan2
- KMT2B | c.1656del p.K553Nfs*52 | Frame Shift Del (DEL) | VAF 13/33 reads (39%) | called by mutect2, pindel, varscan2
- KMT2B | c.6413del p.P2138Rfs*15 | Frame Shift Del (DEL) | VAF 10/44 reads (23%) | called by mutect2, pindel, varscan2
- KMT2D | c.7061del p.P2354Lfs*30 | Frame Shift Del (DEL) | VAF 54/100 reads (54%) | called by mutect2, pindel, varscan2
- KNTC1 | c.4938del p.K1646Nfs*2 | Frame Shift Del (DEL) | VAF 24/56 reads (43%) | called by mutect2, varscan2
- KRT222 | c.650G>A p.G217D | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- LAMC2 | c.1810C>T p.H604Y | Missense Mutation (SNP) | VAF 9/161 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.778); called by muse, mutect2
- LCA5 | c.194C>A p.P65H | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT deleterious (0.03); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- LILRB1 | c.2047T>C p.S683P (on ENST00000427581; = p.S632P on NM_006669.6) | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- LRP1 | c.4271G>A p.R1424H | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- LRP10 | c.1133C>T p.A378V | Missense Mutation (SNP) | VAF 22/30 reads (73%) | SIFT deleterious (0.02); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- LRRC8C | c.188A>G p.Q63R | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT tolerated (0.5); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- LRRIQ1 | c.2339C>T p.A780V | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- LY9 | c.1664C>A p.P555H | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- MAP4K2 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 42/79 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MATR3 | c.708del p.F236Lfs*176 | Frame Shift Del (DEL) | VAF 21/46 reads (46%) | called by mutect2, pindel, varscan2
- MED10 | c.388del p.E130Rfs*14 | Frame Shift Del (DEL) | VAF 38/96 reads (40%) | called by mutect2, pindel, varscan2
- MGA | c.3852T>A p.D1284E | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MICU2 | c.594del p.F198Lfs*7 | Frame Shift Del (DEL) | VAF 8/64 reads (13%) | called by mutect2, pindel
- MKNK1 | c.978G>T p.K326N | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- MOV10 | c.1881C>T p.G627= | Splice Region (SNP) | VAF 7/110 reads (6%) | called by muse, mutect2
- MPRIP | c.1058del p.P353Qfs*30 | Frame Shift Del (DEL) | VAF 71/123 reads (58%) | called by mutect2, varscan2
- MRC2 | c.3656del p.G1219Afs*5 | Frame Shift Del (DEL) | VAF 13/40 reads (33%) | called by mutect2, pindel, varscan2
- MRPS2 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- MSRB3 | c.179A>G p.H60R | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- MTA2 | c.652T>A p.L218M | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MTMR9 | c.1168C>T p.Q390* | Nonsense Mutation (SNP) | VAF 11/41 reads (27%) | called by muse, mutect2, varscan2
- MTREX | c.868C>T p.R290* | Nonsense Mutation (SNP) | VAF 26/70 reads (37%) | called by muse, mutect2, varscan2
- MYOF | c.3998G>A p.C1333Y | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NAPEPLD | c.1128del p.F376Lfs*3 | Frame Shift Del (DEL) | VAF 27/81 reads (33%) | called by mutect2, pindel, varscan2
- NBN | c.1651del p.R551Gfs*8 | Frame Shift Del (DEL) | VAF 13/45 reads (29%) | called by mutect2, pindel, varscan2
- NCOR1 | c.306T>A p.D102E | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.082); called by muse, mutect2
- NDST4 | c.419T>A p.V140D | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- NDUFS1 | c.305T>C p.I102T | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, varscan2
- NEK7 | c.192del p.V65Cfs*6 | Frame Shift Del (DEL) | VAF 23/117 reads (20%) | called by mutect2, pindel, varscan2
- NELFE | c.18del p.G7Dfs*2 | Frame Shift Del (DEL) | VAF 4/40 reads (10%) | called by mutect2, pindel
- NETO2 | c.895A>C p.S299R | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- NFATC1 | c.1348dup p.A450Gfs*21 | Frame Shift Ins (INS) | VAF 22/59 reads (37%) | called by mutect2, pindel, varscan2
- NIPAL3 | c.1057C>T p.Q353* | Nonsense Mutation (SNP) | VAF 39/69 reads (57%) | called by muse, mutect2, varscan2
- NKTR | c.2009del p.N670Ifs*43 | Frame Shift Del (DEL) | VAF 11/36 reads (31%) | called by mutect2, pindel, varscan2
- NOC2L | c.918del p.E307Sfs*35 | Frame Shift Del (DEL) | VAF 43/99 reads (43%) | called by mutect2, pindel, varscan2
- NPC1L1 | c.2514del p.F839Sfs*21 | Frame Shift Del (DEL) | VAF 7/58 reads (12%) | called by mutect2, pindel, varscan2
- NTNG1 | c.961A>G p.T321A | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- NUF2 | c.604del p.T202Rfs*2 | Frame Shift Del (DEL) | VAF 19/120 reads (16%) | called by mutect2, pindel, varscan2
- NUP155 | c.3545T>C p.L1182P (on ENST00000231498 / NM_153485.3; = p.L1123P on NM_004298.4) | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OCRL | c.2102A>G p.K701R | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- OR1E2 | c.169A>C p.T57P | Missense Mutation (SNP) | VAF 47/85 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- OR2T6 | c.326G>T p.G109V | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- OR2W3 | c.266A>G p.D89G | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.356); called by mutect2, varscan2
- OR5F1 | c.536G>A p.C179Y | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR9Q1 | c.250G>A p.V84M | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- PCDH17 | c.1823G>A p.S608N | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- PCDHGA9 | c.712A>G p.N238D | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- PCYT1B | c.950dup p.Q318Afs*49 | Frame Shift Ins (INS) | VAF 28/84 reads (33%) | called by mutect2, pindel, varscan2
- PDGFC | c.533del p.P178Lfs*13 | Frame Shift Del (DEL) | VAF 12/39 reads (31%) | called by mutect2, pindel, varscan2
- PDYN | c.395del p.G132Vfs*14 | Frame Shift Del (DEL) | VAF 25/63 reads (40%) | called by mutect2, pindel, varscan2
- PFKL | c.2297T>C p.L766P | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.188); called by muse, mutect2
- PHACTR2 | c.1555A>G p.R519G | Missense Mutation (SNP) | VAF 37/62 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PHETA1 | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0.05); PolyPhen benign (0.343); called by muse, varscan2
- PHF13 | c.323T>G p.L108R | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT tolerated (0.15); PolyPhen benign (0.289); called by muse, varscan2
- PLCB4 | c.2374C>A p.L792I | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.931); called by muse, mutect2
- PLEC | c.11905G>C p.D3969H (on ENST00000322810 / NM_201380.4; = p.D3859H on NM_000445.5) | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); called by muse, varscan2
- PNLIPRP1 | c.22A>T p.T8S | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- POGK | c.1553T>G p.V518G | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- POGZ | c.1637A>G p.Q546R | Missense Mutation (SNP) | VAF 12/246 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2
- POLE | c.3147G>T p.Q1049H | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- POLR2B | c.1600G>A p.V534I | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- POLR2E | c.16_18del p.E6del | In Frame Del (DEL) | VAF 34/96 reads (35%) | called by pindel, varscan2
- POM121C | c.1567T>C p.W523R (on ENST00000607367; = p.W281R on NM_001099415.3) | Missense Mutation (SNP) | VAF 26/222 reads (12%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- PPARG | c.667G>A p.A223T (on ENST00000287820 / NM_015869.5; = p.A193T on NM_005037.7) | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- PPP1CA | c.637G>A p.V213M | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- PPP1R3F | c.2294A>T p.Q765L | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PQBP1 | c.464G>A p.R155Q | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT tolerated (0.4); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PRKDC | c.4474G>A p.A1492T | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PSAP | c.53C>A p.P18Q | Missense Mutation (SNP) | VAF 39/76 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- PSMB9 | c.373C>T p.Q125* | Nonsense Mutation (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- PTEN | c.35del p.N12Tfs*12 | Frame Shift Del (DEL) | VAF 25/64 reads (39%) | called by mutect2, pindel, varscan2
- PTEN | c.233C>T p.T78I | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- RAB3C | c.510del p.F170Lfs*93 | Frame Shift Del (DEL) | VAF 14/29 reads (48%) | called by mutect2, pindel, varscan2
- RAE1 | c.743del p.P248Rfs*29 | Frame Shift Del (DEL) | VAF 28/67 reads (42%) | called by mutect2, pindel, varscan2
- RAVER1 | c.1438del p.L480Cfs*55 (on ENST00000615032; = p.L636Cfs*55 on NM_133452.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 26/98 reads (27%) | called by mutect2, pindel
- RCC2 | c.739G>A p.A247T | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.029); called by muse, mutect2
- RELN | c.1099G>C p.V367L | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- RHPN2 | c.469-1G>T p.X157_splice | Splice Site (SNP) | VAF 28/60 reads (47%) | called by muse, mutect2
- RNF113A | c.944C>T p.A315V | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- RNF113B | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RNF213 | c.15433del p.Q5145Kfs*14 | Frame Shift Del (DEL) | VAF 25/68 reads (37%) | called by mutect2, pindel, varscan2
- RPL24 | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RPL9 | c.568G>A p.A190T | Missense Mutation (SNP) | VAF 78/175 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- RREB1 | c.2141G>A p.C714Y | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- RTKN | c.348dup p.C117Lfs*9 (on ENST00000272430 / NM_001015055.2; = p.C104Lfs*9 on NM_033046.2) | Frame Shift Ins (INS) | VAF 36/87 reads (41%) | called by mutect2, pindel, varscan2
- RTP1 | c.104A>G p.E35G | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); called by muse, mutect2
- SACS | c.2562del p.K854Nfs*2 | Frame Shift Del (DEL) | VAF 34/84 reads (40%) | called by mutect2, pindel, varscan2
- SALL3 | c.2138G>A p.G713D | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SAMD9L | c.4306C>T p.P1436S | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- SCAF4 | c.2159C>A p.P720H | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- SCN11A | c.2647dup p.L883Pfs*30 | Frame Shift Ins (INS) | VAF 11/45 reads (24%) | called by mutect2, pindel, varscan2
- SCN3A | c.3964A>C p.R1322= | Splice Region (SNP) | VAF 12/26 reads (46%) | called by muse, mutect2, varscan2
- SCYL3 | c.2019G>T p.M673I (on ENST00000367770; = p.M619I on NM_020423.7) | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SELENOS | c.101G>A p.G34D | Missense Mutation (SNP) | VAF 64/113 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SETDB1 | c.1475C>T p.T492M | Missense Mutation (SNP) | VAF 49/172 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SF3B3 | c.3500_3502del p.Y1167del | In Frame Del (DEL) | VAF 28/56 reads (50%) | called by pindel, varscan2
- SFMBT2 | c.688G>A p.D230N | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.3); called by muse, mutect2
- SHC1 | c.514G>A p.V172I (on ENST00000368445 / NM_183001.5; = p.V62I on NM_003029.5) | Missense Mutation (SNP) | VAF 54/185 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- SHROOM4 | c.269+2T>C p.X90_splice | Splice Site (SNP) | VAF 5/36 reads (14%) | called by muse, mutect2, varscan2
- SLAMF7 | c.492G>A p.W164* | Nonsense Mutation (SNP) | VAF 19/56 reads (34%) | called by muse, mutect2, varscan2
- SLC27A4 | c.862del p.L288Sfs*19 | Frame Shift Del (DEL) | VAF 10/57 reads (18%) | called by mutect2, pindel, varscan2
- SLC35B1 | c.817T>C p.Y273H (on ENST00000649906; = p.Y236H on NM_005827.4) | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.79); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SLC38A3 | c.892G>A p.V298I | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- SLC39A8 | c.1336G>A p.A446T | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- SLC6A14 | c.1241dup p.M415Hfs*15 | Frame Shift Ins (INS) | VAF 11/22 reads (50%) | called by mutect2, varscan2
- SMG6 | c.2339G>T p.R780M | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SMYD1 | c.1007T>C p.L336P | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- SOBP | c.2521G>A p.A841T | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- SORBS1 | c.2798del p.N933Tfs*59 (on ENST00000361941 / NM_001034954.2; = p.N583Tfs*97 on NM_006434.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 10/63 reads (16%) | called by mutect2, pindel, varscan2
- SPPL2C | c.136T>C p.Y46H | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SPTA1 | c.2669G>T p.R890M | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); called by muse, mutect2
- SPTBN1 | c.5042C>T p.A1681V | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.662); called by muse, mutect2
- SSR1 | c.528C>A p.N176K | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); called by muse, mutect2
- SSU72P8 | c.289dup p.R97Kfs*7 | Frame Shift Ins (INS) | VAF 61/154 reads (40%) | called by mutect2, pindel, varscan2
- ST13 | c.470T>A p.V157D | Missense Mutation (SNP) | VAF 60/126 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ST14 | c.1976T>C p.I659T | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.39); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- STAB2 | c.6998C>T p.A2333V | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- STAT4 | c.1240A>G p.K414E | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); called by muse, mutect2
- STIL | c.2630_2631del p.V877Efs*5 | Frame Shift Del (DEL) | VAF 24/68 reads (35%) | called by pindel, varscan2
- SUPT5H | c.2688del p.S897Pfs*57 | Frame Shift Del (DEL) | VAF 27/81 reads (33%) | called by mutect2, pindel, varscan2
- SYN1 | c.457C>A p.L153I | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- SZT2 | c.9398del p.G3133Afs*108 (on ENST00000634258 / NM_001365999.1; = p.G3076Afs*108 on NM_015284.4) | Frame Shift Del (DEL) | VAF 22/58 reads (38%) | called by mutect2, pindel, varscan2
- TACC2 | c.5613del p.A1872Qfs*8 (on ENST00000334433; = p.A63Qfs*8 on NM_206861.3) | Frame Shift Del (DEL) | VAF 12/84 reads (14%) | called by mutect2, pindel, varscan2
- TBX5 | c.685A>G p.N229D | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- TCOF1 | c.4046T>C p.L1349P (on ENST00000377797 / NM_001135243.1; = p.L1272P on NM_000356.4) | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TECPR1 | c.3286G>A p.V1096M | Missense Mutation (SNP) | VAF 41/82 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- THAP3 | c.157G>A p.V53I | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- THSD7A | c.1077dup p.E360Rfs*19 | Frame Shift Ins (INS) | VAF 10/26 reads (38%) | called by mutect2, pindel, varscan2
- THSD7B | c.1794C>A p.C598* | Nonsense Mutation (SNP) | VAF 36/66 reads (55%) | called by muse, mutect2, varscan2
- TMC5 | c.2465C>A p.P822H (on ENST00000396229 / NM_001105248.1; = p.P576H on NM_024780.5) | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMED9 | c.558+1G>A p.X186_splice | Splice Site (SNP) | VAF 12/48 reads (25%) | called by muse, mutect2, varscan2
- TMEM108 | c.1570C>G p.L524V | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- TMEM79 | c.487del p.R163Gfs*17 | Frame Shift Del (DEL) | VAF 25/126 reads (20%) | called by mutect2, pindel, varscan2
- TMIGD2 | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- TMPRSS9 | c.1255-1G>T p.X419_splice (on ENST00000648592; = p.X385_splice on NM_182973.2) | Splice Site (SNP) | VAF 45/96 reads (47%) | called by muse, mutect2, varscan2
- TNXB | c.12019del p.R4007Vfs*56 (on ENST00000647633; = p.R3760Vfs*56 on NM_019105.8 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 14/109 reads (13%) | called by mutect2, pindel, varscan2
- TPSAB1 | c.674G>A p.G225E | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TRIM39 | c.803del p.K268Rfs*25 | Frame Shift Del (DEL) | VAF 35/99 reads (35%) | called by mutect2, pindel, varscan2
- TSPYL1 | c.440G>A p.G147E | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2
- TTC21A | c.3881A>G p.N1294S | Missense Mutation (SNP) | VAF 34/61 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- TTYH2 | c.1213A>G p.T405A | Missense Mutation (SNP) | VAF 27/39 reads (69%) | SIFT tolerated (0.59); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TULP4 | c.2647del p.L883Wfs*43 | Frame Shift Del (DEL) | VAF 8/76 reads (11%) | called by mutect2, pindel, varscan2
- TXLNA | c.479A>C p.Q160P | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- UBB | c.570del p.D191Tfs*35 | Frame Shift Del (DEL) | VAF 44/113 reads (39%) | called by mutect2, pindel, varscan2
- ULK2 | c.834del p.K278Nfs*130 | Frame Shift Del (DEL) | VAF 52/147 reads (35%) | called by mutect2, pindel, varscan2
- UNKL | c.535C>T p.P179S | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- USP13 | c.353del p.L118* | Frame Shift Del (DEL) | VAF 21/74 reads (28%) | called by mutect2, pindel, varscan2
- USP31 | c.2677G>A p.A893T | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- USP48 | c.1926G>T p.E642D | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- UTRN | c.4078C>A p.L1360I | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- VENTX | c.596del p.P199Lfs*96 | Frame Shift Del (DEL) | VAF 28/68 reads (41%) | called by mutect2, varscan2
- WDCP | c.472C>A p.R158S | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- WDR20 | c.565del p.H189Tfs*5 | Frame Shift Del (DEL) | VAF 31/79 reads (39%) | called by mutect2, pindel, varscan2
- XIRP1 | c.2573A>G p.K858R | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- YLPM1 | c.530del p.P177Rfs*42 | Frame Shift Del (DEL) | VAF 14/70 reads (20%) | called by mutect2, varscan2
- ZAN | c.2803A>G p.T935A | Missense Mutation (SNP) | VAF 18/320 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.117); called by muse, mutect2
- ZAP70 | c.1292A>G p.E431G | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ZBTB6 | c.631G>T p.G211C | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- ZC3H12A | c.1315G>T p.G439C | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZDHHC18 | c.727_728del p.S243Pfs*67 | Frame Shift Del (DEL) | VAF 32/88 reads (36%) | called by pindel, varscan2
- ZER1 | c.1175G>A p.R392Q | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- ZFHX3 | c.6140del p.P2047Lfs*54 | Frame Shift Del (DEL) | VAF 15/42 reads (36%) | called by mutect2, pindel, varscan2
- ZHX1 | c.312T>A p.C104* | Nonsense Mutation (SNP) | VAF 18/26 reads (69%) | called by muse, mutect2, varscan2
- ZNF14 | c.80del p.K27Sfs*6 | Frame Shift Del (DEL) | VAF 33/88 reads (38%) | called by mutect2, pindel, varscan2
- ZNF268 | c.419G>A p.C140Y | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZNF317 | c.274A>G p.N92D | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- ZNF324B | c.644C>T p.A215V | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- ZNF416 | c.693del p.H232Tfs*54 | Frame Shift Del (DEL) | VAF 30/78 reads (38%) | called by mutect2, pindel, varscan2
- ZNF462 | c.4318C>T p.Q1440* | Nonsense Mutation (SNP) | VAF 26/39 reads (67%) | called by muse, mutect2, varscan2
- ZNF536 | c.2521del p.A841Pfs*45 | Frame Shift Del (DEL) | VAF 18/48 reads (38%) | called by mutect2, pindel, varscan2
- ZNRF1 | c.199dup p.V67Gfs*46 | Frame Shift Ins (INS) | VAF 10/22 reads (45%) | called by mutect2, varscan2
- ZNRF3 | c.2801del p.P934Rfs*22 (on ENST00000544604 / NM_001206998.2; = p.P834Rfs*22 on NM_032173.3) | Frame Shift Del (DEL) | VAF 6/50 reads (12%) | called by mutect2, pindel, varscan2
- A4GALT | c.312T>C p.T104= | Silent (SNP) | VAF 21/119 reads (18%) | called by muse, mutect2, varscan2
- ABHD16B | c.111C>T p.D37= | Silent (SNP) | VAF 18/33 reads (55%) | called by muse, mutect2, varscan2
- AC231657.3 | c.759G>A p.S253= | Silent (SNP) | VAF 24/58 reads (41%) | called by muse, mutect2, varscan2
- ACADS | c.477C>T p.N159= | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as rs747915680; called by muse, mutect2, varscan2
- ADAMTS1 | c.1443G>A p.S481= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as rs771153194, COSV53171897, COSV99535938; called by mutect2, varscan2
- ADORA2B | c.549A>C p.V183= | Silent (SNP) | VAF 31/66 reads (47%) | called by muse, mutect2, varscan2
- AGAP6 | c.372A>G p.T124= (on ENST00000374056 / NM_001365867.1; = p.T147= on NM_001077665.2) | Silent (SNP) | VAF 53/435 reads (12%) | catalogued as rs1473379620; called by muse, mutect2, varscan2
- AGO2 | c.1500C>T p.S500= | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as rs755823222; called by muse, varscan2
- AGR3 | c.39C>T p.L13= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as rs150179457; called by muse, mutect2, varscan2
- AIFM1 | c.87G>A p.R29= | Silent (SNP) | VAF 11/138 reads (8%) | called by muse, mutect2
- AJM1 | c.939G>A p.E313= | Silent (SNP) | VAF 49/132 reads (37%) | called by muse, mutect2, varscan2
- AKNAD1 | c.51G>A p.L17= | Silent (SNP) | VAF 24/47 reads (51%) | called by muse, mutect2, varscan2
- ALPK2 | c.5178A>C p.G1726= | Silent (SNP) | VAF 31/75 reads (41%) | called by muse, mutect2, varscan2
- ANKRD12 | c.483G>A p.T161= | Silent (SNP) | VAF 21/54 reads (39%) | catalogued as rs371533373, COSV50829283; called by muse, mutect2, varscan2
- ANKS1A | c.2128C>T p.L710= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as COSV64461862; called by muse, mutect2, varscan2
- ANXA6 | c.402C>T p.Y134= | Silent (SNP) | VAF 28/64 reads (44%) | called by muse, mutect2, varscan2
- AP2M1 | c.1242C>T p.S414= | Silent (SNP) | VAF 28/68 reads (41%) | catalogued as rs778990308, COSV53050036; called by muse, mutect2, varscan2
- APCDD1L | c.120C>A p.P40= | Silent (SNP) | VAF 26/84 reads (31%) | called by muse, mutect2, varscan2
- ARFIP1 | c.303C>T p.G101= (on ENST00000353617 / NM_001287432.1; = p.G69= on NM_014447.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as rs545518935; called by muse, mutect2, varscan2
- ARHGAP25 | c.1245C>T p.S415= (on ENST00000409202 / NM_001007231.3; = p.S407= on NM_014882.3) | Silent (SNP) | VAF 36/74 reads (49%) | catalogued as rs375050207, COSV54898183; called by muse, mutect2, varscan2
- ARHGAP35 | c.3514C>A p.R1172= | Silent (SNP) | VAF 11/61 reads (18%) | called by muse, mutect2, varscan2
- ARHGAP44 | c.1992G>T p.G664= | Silent (SNP) | VAF 40/77 reads (52%) | catalogued as rs758008915; called by muse, mutect2, varscan2
- ARHGEF10L | c.3633C>T p.Y1211= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as rs1184882713; called by muse, mutect2, varscan2
- ARID1A | c.5769C>T p.T1923= | Silent (SNP) | VAF 30/80 reads (38%) | catalogued as rs753993188; called by muse, mutect2, varscan2
- ARID5B | c.510C>T p.D170= | Silent (SNP) | VAF 26/60 reads (43%) | catalogued as rs370897671; called by muse, mutect2, varscan2
- ARL11 | c.207G>A p.P69= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as rs745917227, COSV56291056; called by muse, mutect2, varscan2
- ARMH3 | c.204T>C p.G68= | Silent (SNP) | VAF 23/51 reads (45%) | called by muse, mutect2, varscan2
- ASMTL | c.246C>T p.D82= | Silent (SNP) | VAF 20/244 reads (8%) | catalogued as rs190761175; called by muse, mutect2
- ASXL3 | c.4816C>A p.R1606= | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as COSV52469282; called by muse, mutect2, varscan2
- ATR | c.4344G>A p.E1448= | Silent (SNP) | VAF 46/95 reads (48%) | called by muse, mutect2, varscan2
- BCOR | c.4902C>T p.S1634= (on ENST00000378444 / NM_001123385.2; = p.S1600= on NM_017745.6) | Silent (SNP) | VAF 32/79 reads (41%) | catalogued as rs747409134, COSV60716874; ClinVar: likely benign; called by muse, mutect2, varscan2
- BIRC6 | c.13137T>C p.N4379= | Silent (SNP) | VAF 16/38 reads (42%) | called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.3195T>C p.H1065= | Silent (SNP) | VAF 25/40 reads (63%) | called by muse, mutect2, varscan2
- BNC2 | c.2466A>C p.P822= | Silent (SNP) | VAF 11/20 reads (55%) | called by muse, varscan2
- BSG | c.945G>A p.T315= | Silent (SNP) | VAF 24/57 reads (42%) | catalogued as rs773330019, COSV100344718; called by muse, mutect2, varscan2
- C11orf54 | c.906C>T p.R302= (on ENST00000331239; = p.R252= on NM_014039.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/52 reads (48%) | catalogued as rs1174457054; called by muse, mutect2, varscan2
- C4A | c.2676C>A p.G892= | Silent (SNP) | VAF 7/43 reads (16%) | called by mutect2, varscan2
- CADM3 | c.579G>A p.S193= (on ENST00000368125 / NM_001127173.3; = p.S227= on NM_021189.5) | Silent (SNP) | VAF 26/111 reads (23%) | catalogued as rs773654084, COSV100930272, COSV63685776; called by muse, mutect2, varscan2
- CCDC57 | c.2217G>A p.S739= | Silent (SNP) | VAF 61/114 reads (54%) | catalogued as rs766352361; called by muse, mutect2, varscan2
- CCNF | c.900C>T p.S300= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as rs543971984; called by muse, mutect2, varscan2
- CDCA7 | c.597G>A p.E199= (on ENST00000347703 / NM_145810.3; = p.E278= on NM_031942.5) | Silent (SNP) | VAF 43/96 reads (45%) | catalogued as COSV60720730; called by muse, mutect2, varscan2
- CDH13 | c.1489C>T p.L497= | Silent (SNP) | VAF 16/65 reads (25%) | catalogued as COSV51837021; called by muse, mutect2, varscan2
- CEACAM5 | c.1989C>T p.G663= | Silent (SNP) | VAF 30/55 reads (55%) | called by muse, mutect2, varscan2
- CEP350 | c.2064G>T p.G688= | Silent (SNP) | VAF 32/135 reads (24%) | called by muse, mutect2, varscan2
- CHRM4 | c.357C>T p.S119= | Silent (SNP) | VAF 14/25 reads (56%) | catalogued as rs199710790; called by muse, mutect2, varscan2
- CHTOP | c.624C>T p.R208= | Silent (SNP) | VAF 54/240 reads (23%) | catalogued as rs1195139716; called by muse, varscan2
- COA3 | c.183C>T p.G61= | Silent (SNP) | VAF 33/68 reads (49%) | catalogued as COSV55907334; called by muse, mutect2, varscan2
- COPA | c.1479C>T p.Y493= | Silent (SNP) | VAF 16/117 reads (14%) | catalogued as rs1299072491, COSV99616261; called by muse, mutect2, varscan2
- CRACD | c.1929C>T p.G643= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as rs752102687; called by muse, mutect2, varscan2
- CRTAC1 | c.1971C>T p.C657= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as rs773387702, COSV54001784, COSV54008445; called by mutect2, varscan2
- DDR1 | c.765T>C p.Y255= | Silent (SNP) | VAF 36/84 reads (43%) | catalogued as rs763953188; called by muse, mutect2, varscan2
- DDX23 | c.1626C>T p.R542= | Silent (SNP) | VAF 30/81 reads (37%) | called by muse, mutect2, varscan2
- DENND3 | c.105C>T p.G35= | Silent (SNP) | VAF 23/121 reads (19%) | catalogued as rs200233804; called by muse, mutect2, varscan2
- DGCR8 | c.1749G>A p.Q583= | Silent (SNP) | VAF 17/38 reads (45%) | called by muse, mutect2, varscan2
- DHX38 | c.834C>T p.A278= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as rs757149271; called by muse, mutect2, varscan2
- DSPP | c.2493C>T p.D831= | Silent (SNP) | VAF 68/138 reads (49%) | called by muse, mutect2, varscan2
- EFL1 | c.2211C>T p.D737= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as rs374555583; called by muse, mutect2, varscan2
- EHMT1 | c.165T>C p.N55= | Silent (SNP) | VAF 19/53 reads (36%) | called by muse, mutect2, varscan2
- EPOR | c.234C>T p.S78= | Silent (SNP) | VAF 18/248 reads (7%) | called by muse, mutect2
- ERF | c.87G>A p.L29= | Silent (SNP) | VAF 19/42 reads (45%) | called by muse, mutect2, varscan2
- ETV3L | c.90C>T p.A30= | Silent (SNP) | VAF 29/115 reads (25%) | catalogued as rs750838692, COSV71901203; called by muse, mutect2, varscan2
- FAAH | c.630C>A p.S210= | Silent (SNP) | VAF 9/80 reads (11%) | called by muse, mutect2, varscan2
- FAM155B | c.786C>T p.D262= | Silent (SNP) | VAF 84/168 reads (50%) | called by muse, mutect2, varscan2
- FBXO39 | c.231A>G p.S77= | Silent (SNP) | VAF 8/43 reads (19%) | called by muse, mutect2, varscan2
- FGA | c.99C>T p.G33= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as rs758959148, COSV57394283; called by mutect2, varscan2
- GABRG2 | c.570C>T p.C190= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs564464466; called by muse, mutect2, varscan2
- GET4 | c.759G>A p.T253= | Silent (SNP) | VAF 31/68 reads (46%) | catalogued as rs148309614, COSV99763084; called by muse, mutect2, varscan2
- GGT6 | c.193C>T p.L65= | Silent (SNP) | VAF 29/75 reads (39%) | called by muse, mutect2, varscan2
- GRIK3 | c.2490C>T p.A830= | Silent (SNP) | VAF 25/50 reads (50%) | catalogued as rs1286130278; called by muse, mutect2, varscan2
- GRM5 | c.3525G>A p.S1175= (on ENST00000305447 / NM_001143831.2; = p.S1143= on NM_000842.4) | Silent (SNP) | VAF 27/55 reads (49%) | catalogued as COSV100549770; called by muse, mutect2, varscan2
- GRXCR1 | c.825G>A p.T275= | Silent (SNP) | VAF 36/80 reads (45%) | catalogued as rs370629848; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- H1-8 | c.573C>T p.G191= | Silent (SNP) | VAF 44/83 reads (53%) | catalogued as rs761850265; called by muse, mutect2, varscan2
- HELZ | c.5154G>A p.Q1718= | Silent (SNP) | VAF 26/53 reads (49%) | called by muse, mutect2, varscan2
- HERC2 | c.11691T>C p.F3897= | Silent (SNP) | VAF 7/113 reads (6%) | called by muse, mutect2
- IFIT3 | c.1419C>T p.G473= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as rs765362853, COSV51080266; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1113G>A p.L371= | Silent (SNP) | VAF 4/27 reads (15%) | called by muse, mutect2, varscan2
- IL4R | c.2163C>T p.C721= | Silent (SNP) | VAF 52/111 reads (47%) | catalogued as rs747836187; called by muse, mutect2, varscan2
- IPO8 | c.2973G>A p.L991= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as COSV56246443; called by muse, mutect2, varscan2
- ISCU | c.213C>T p.D71= (on ENST00000311893 / NM_213595.4; = p.D46= on NM_014301.4) | Silent (SNP) | VAF 36/84 reads (43%) | catalogued as rs201875179; called by muse, mutect2, varscan2
- ITGA2B | c.1749T>A p.L583= | Silent (SNP) | VAF 23/55 reads (42%) | called by muse, mutect2, varscan2
- ITGAL | c.3156C>T p.C1052= | Silent (SNP) | VAF 34/56 reads (61%) | called by muse, mutect2, varscan2
- JSRP1 | c.549G>A p.A183= | Silent (SNP) | VAF 42/99 reads (42%) | catalogued as rs1331831050; called by muse, mutect2, varscan2
- KIF1C | c.1296G>A p.E432= | Silent (SNP) | VAF 7/46 reads (15%) | called by muse, mutect2, varscan2
- KLF2 | c.909C>T p.H303= | Silent (SNP) | VAF 40/91 reads (44%) | catalogued as rs988616027; called by muse, mutect2, varscan2
- LFNG | c.765C>T p.G255= (on ENST00000222725 / NM_001040167.2; = p.G126= on NM_002304.2) | Silent (SNP) | VAF 26/45 reads (58%) | catalogued as rs201724400; called by muse, mutect2, varscan2
- LIPE | c.1335C>T p.G445= | Silent (SNP) | VAF 27/99 reads (27%) | catalogued as rs535154534, COSV54922735; called by muse, mutect2, varscan2
- LMTK3 | c.693G>A p.L231= | Silent (SNP) | VAF 15/29 reads (52%) | called by muse, mutect2, varscan2
- LRRC8A | c.1272G>A p.A424= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as rs745809785; called by muse, varscan2
- LY75 | c.4062T>C p.T1354= | Silent (SNP) | VAF 27/95 reads (28%) | called by muse, mutect2, varscan2
- MACF1 | c.5569C>T p.L1857= | Silent (SNP) | VAF 10/21 reads (48%) | called by muse, mutect2, varscan2
- MAP3K15 | c.534T>C p.S178= | Silent (SNP) | VAF 23/61 reads (38%) | called by muse, mutect2, varscan2
- MCHR1 | c.78G>A p.E26= | Silent (SNP) | VAF 51/96 reads (53%) | called by muse, mutect2, varscan2
- MCM3AP | c.150G>T p.S50= | Silent (SNP) | VAF 39/69 reads (57%) | called by muse, mutect2, varscan2
- METRNL | c.345G>A p.S115= | Silent (SNP) | VAF 34/71 reads (48%) | catalogued as rs1270951307, COSV100193695; called by muse, mutect2, varscan2
- METTL24 | c.327G>T p.R109= | Silent (SNP) | VAF 85/154 reads (55%) | called by muse, mutect2, varscan2
- MFSD2B | c.1041G>A p.T347= | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as rs761690403; called by muse, varscan2
- MFSD6 | c.1644G>A p.A548= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs1040500148, COSV55620924; called by muse, mutect2, varscan2
- MRPL44 | c.171C>T p.P57= | Silent (SNP) | VAF 30/61 reads (49%) | called by muse, mutect2, varscan2
- MUC4 | c.16014G>A p.L5338= (on ENST00000463781 / NM_018406.7; = p.L1102= on NM_004532.6) | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs1560211974; called by muse, mutect2, varscan2
97 further variants in this file (0 protein-altering or splice-affecting, 78 silent, 19 other) are not listed here.
